Gene-level copy-number profile of tumor specimen TCGA-GV-A3JZ-01A from TCGA case TCGA-GV-A3JZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 55.9 years (20,420 days).
Specimen TCGA-GV-A3JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d1035d87-3065-4efd-812a-76893fd722bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3JZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56a0654a-d332-4b8d-8977-2452f071b71c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 1,517; copy number 2: 13,365; copy number 3: 20,222; copy number 4: 14,611; copy number 5: 5,097; copy number 6: 2,190; copy number 7: 1,105; copy number 8: 909; copy number 9: 93; copy number 10: 143; copy number 11: 331; copy number 13: 1; copy number 14: 104; copy number 18: 10; copy number 19: 17; copy number 20: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3JZ-01A-11D-A219-01): tumor purity 0.82, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:10,699,015–12,215,267, 28 genes (within-gene range 0–2): TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:19,203,825–19,756,207, 40 genes: AC106017.1, KYNUP3, EPN2, AC106017.2, EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,730 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–151,805,419, 119 genes, copy number 7 (broad region; genes not listed).
- chr1:157,092,043–164,357,364, 248 genes, copy number 7–10 (broad region; genes not listed).
- chr5:58,198–3,181,487, 87 genes, copy number 11 (broad region; genes not listed).
- chr5:10,971,836–11,904,446, 1 gene, copy number 7 (within-gene range 5–7): CTNND2.
- chr5:12,297,399–17,670,571, 98 genes, copy number 7–8 (broad region; genes not listed).
- chr6:7,481,094–8,102,559, 15 genes, copy number 7–10: HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1.
- chr6:11,503,509–11,644,343, 5 genes, copy number 9: RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP.
- chr6:12,008,762–15,999,797, 49 genes, copy number 9–14 (within-gene range 1–14): HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543.
- chr6:19,638,040–25,885,751, 97 genes, copy number 11–20 (broad region; genes not listed).
- chr6:26,871,484–27,473,118, 27 genes, copy number 14: GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4.
- chr6:32,352,877–32,352,983, 1 gene, copy number 13: RNU6-603P.
- chr6:35,733,867–35,797,344, 6 genes, copy number 7–9: AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS.
- chr6:36,493,892–38,154,624, 44 genes, copy number 8–14 (within-gene range 3–14): STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:43,427,366–44,378,957, 44 genes, copy number 7 (within-gene range 4–7): ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2.
- chr6:46,652,915–47,042,350, 10 genes, copy number 18: SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:57,855,891–58,438,364, 13 genes, copy number 8: AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr7:14,814,131–17,467,256, 37 genes, copy number 7–9 (within-gene range 6–9): AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr7:33,868,501–36,724,549, 51 genes, copy number 7 (within-gene range 6–7): AC008080.3, BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1.
- chr7:36,854,361–37,449,249, 1 gene, copy number 7 (within-gene range 6–7): ELMO1.
- chr7:37,116,779–48,647,497, 208 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:52,891,837–53,036,925, 3 genes, copy number 8: SGO1P2, AC074397.1, POM121L12.
- chr8:41,261,962–50,796,692, 152 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:104,330,324–145,066,685, 599 genes, copy number 8 (broad region; genes not listed).
- chr9:14,475–12,058,227, 159 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr9:33,247,820–43,045,120, 348 genes, copy number 7 (broad region; genes not listed).
- chr10:21,110,682–22,003,769, 22 genes, copy number 7: NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1, MLLT10, AL358780.1, RNU6-306P, HNRNPRP1, RNU6-1141P, DNAJC1, RN7SKP219, AL359697.1, RN7SKP37.
- chr15:23,083,094–24,090,821, 26 genes, copy number 9 (within-gene range 5–9): ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:57,375,967–58,569,844, 26 genes, copy number 11 (within-gene range 3–11): CGNL1, RNU6-844P, AC025271.3, AC025271.2, AC025271.4, AC025271.1, MYZAP, GCOM1, POLR2M, AC090651.1, ALDH1A2, AC012653.1, AC012653.2, AC025431.1, AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23, AC066616.1, LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2.
- chr17:17,776,686–18,363,563, 28 genes, copy number 7 (within-gene range 6–7): SMCR5, AC122129.2, SREBF1, MIR6777, MIR33B, TOM1L2, AC122129.1, DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2, GID4, DRG2, AC087164.2, MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778.
- chr17:21,655,843–22,332,410, 13 genes, copy number 8: AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:39,238,466–41,168,221, 106 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr18:11,326,270–11,552,847, 7 genes, copy number 7: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1.
- chr18:31,622,247–32,745,567, 34 genes, copy number 7 (within-gene range 4–7): B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1.
- chr19:29,526,499–32,073,809, 38 genes, copy number 11–14: VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533.
- chr22:29,327,680–29,478,868, 8 genes, copy number 7 (within-gene range 4–7): AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1.

Autosomal genes at a single copy (total copy number 1): 1,382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
